Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4822, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4822-01A (Primary Tumor).

FINAL DIAGNOSIS

CGA-B0-4822

KIDNEY, RIGHT, LAPAROSCOPIC NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CLEAR CELL (CONVENTIONAL CELL) TYPE, FUHRMAN GRADE 4 OF 4, WITH AREAS OF SPINDLE CELL DIFFERENTIATION, 13.2 cm IN LARGEST DIAMETER.
- B. THE CARCINOMA INVADES INTO, BUT NOT THROUGH THE RENAL CAPSULE.
- C. ALL SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- D. ADRENAL GLAND IS PRESENT; NO NEOPLASIA IS SEEN IN THE ADRENAL GLAND.
- E. pTNM STAGE (5th edition) = pT2, NX, MX.

Final Diagnosis

NON-GYN CYTOLOGY

Diagnosis:

NO MALIGNANT CELLS SEEN

Source: NCI Genomic Data Commons file 79c50487-1b0a-4c0c-893c-ea87fe6a9375 (TCGA-B0-4822.8B63BAC6-B4BE-4D0C-80C8-2647DF4015E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).